Gene-level copy-number profile of tumor specimen ALCH-B1UU-TTP1-A from ALCHEMIST case ALCH-B1UU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.3 years (26,786 days).
Specimen ALCH-B1UU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file efd29aa9-0129-43c8-a062-c32b7a689097.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1UU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/89bb9de2-edc0-4c63-a641-6c7dffe076a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 4,879; copy number 2: 53,870; copy number 3: 98; copy number 4: 36; copy number 5: 2; copy number 7: 1; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:22,670,201–22,670,711, 1 gene: AC092421.1.
- chr8:22,042,398–22,048,809, 1 gene: FGF17.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,811,850–2,812,692, 1 gene, copy number 5: AL592464.2.
- chr9:64,439,346–64,463,196, 2 genes, copy number 5–7: SNX18P9, CR769776.2.
- chr21:44,133,610–44,210,114, 1 gene, copy number 9 (within-gene range 2–9): GATD3A.

Autosomal genes at a single copy (total copy number 1): 2,044. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
